Surgical pathology report (de-identified scan), TCGA case TCGA-GS-A9TU, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Fundacio Clinic per a la Recerca Biomedica, specimen TCGA-GS-A9TU-01A (Primary Tumor).

Lymph node of 3,6x2,5x1,6 cm. The surface is smooth and whitish.

LEFT INGUINAL LYMPH NODE (BIOPSY)

- DIFFUSE LARGE B-CELL LYMPHOMA WITH FOCAL PLASMOCELLULAR DIFFERENTIATION.

The lymph node shows a practically complete substitution of the normal tissue by a diffuse lymphoid proliferation of large cells, showing occasionally plasmocellular differentiation.

The immunohistochemical study shows that the neoplastic cells are positive for CD20, CD79a, CD43 BCL2, BCL6 and MUM1 and negative for CD3, CD5, CD10, CD23, CD21 and p53. The cells show kappa light chain restriction. The Ki67 proliferation index is approximately around 60%.

No rearrangement of the BCL2 gene by PCR (MBR MCR) has been observed

ICD O-3

Lymphoma, diffuse large B cell NOS
9680/3
Site: Lymph node, inguinal
077.4

9/3/14

Source: NCI Genomic Data Commons file 06170c34-d46a-42fd-b7cc-7eb984e5dcb0 (TCGA-GS-A9TU.4311425D-5160-4EED-BE1F-8532320AAF39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).